Somatic mutation profile of tumor specimen BA2112D (aliquot aq-BA2112D) from BEATAML1.0 case 2048, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 29.6 years (10,826 days).
Specimen BA2112D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5e8e535-95c9-4979-a528-2bf6b7b4d4b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2137D (Solid Tissue Normal), aliquot aq-BA2137D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd1e8605-8845-439f-92d5-25422e021afd

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 3, Frame Shift Ins 1, 5'Flank 1, Frame Shift Del 1, RNA 1, Silent 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 66/358 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 75/448 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COCH | c.1165C>T p.R389W (on ENST00000216361 / NM_001347720.1; = p.R324W on NM_004086.3) | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs776982710, COSV53552146; called by muse, mutect2, varscan2
- FCGBP | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs779220407; called by muse, mutect2
- GRK1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.737); catalogued as rs1381689665; called by muse, mutect2, varscan2
- KDM6A | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 60/164 reads (37%) | catalogued as COSV100938725; called by muse, mutect2, varscan2
- PERM1 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1160965040, COSV100379051; called by muse, mutect2, varscan2
- PRSS21 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.065); catalogued as COSV50052495; called by muse, mutect2, varscan2
- PRSS53 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); catalogued as rs1244615124; called by muse, mutect2
- SHISA6 | c.1417C>T p.R473C (on ENST00000409168 / NM_001173461.1; = p.R524C on NM_207386.4) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1490636531; called by muse, mutect2, varscan2
- BSN | c.5615C>A p.A1872E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- CD44 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CRB2 | c.1561C>A p.Q521K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FMO3 | c.405dup p.E136Rfs*6 | Frame Shift Ins (INS) | VAF 59/324 reads (18%) | called by mutect2, pindel, varscan2
- IDH2 | c.675C>G p.D225E | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- NTN5 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- OSBPL6 | c.2715T>A p.N905K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PPP1CA | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RBKS | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, mutect2
- SMIM24 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SPEG | c.3382A>G p.S1128G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRGJ2 | c.1_2del p.N2Lfs*3 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, pindel*, varscan2*
- TRGJP2 | c.1_5delinsTGGGG p.S2G | Missense Mutation (ONP) | VAF 8/59 reads (14%) | called by mutect2*, pindel
- PEG3 | c.3057C>T p.Y1019= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs756262819, COSV55631928; called by muse, mutect2, varscan2
- ADGRE4P | n.121C>T | RNA (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- C12orf42 | c.259+819C>T | Intron (SNP) | VAF 20/108 reads (19%) | catalogued as rs1285140310; called by muse, mutect2, varscan2
- HPCAL1 | c.484+18C>A | Intron (SNP) | VAF 4/53 reads (8%) | catalogued as COSV57144372; called by muse, mutect2
- PLOD2 | chr3:146163620 T>G | 5'Flank (SNP) | VAF 44/220 reads (20%) | called by muse, mutect2, varscan2
- PLSCR1 | c.355+31A>G | Intron (SNP) | VAF 24/117 reads (21%) | catalogued as rs369897901; called by muse, mutect2, varscan2
- SERINC3 | c.-30G>T | 5'UTR (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
